FM case AD7981 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/4f1ed224-6d19-4e6f-a0fd-8e3a65df6514

Female, 35.3 years: Medullary carcinoma, NOS (ICD-O-3 8510/3) of the thyroid gland. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
